CCDI case PBBUBH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8bef0d5a-2dab-4d0f-94e9-699043aec4d2

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.2 years (1,528 days).

Biospecimens (3 samples)
- Sample 0DGYZ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGZAC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGZFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
